Gene-level copy-number profile of tumor specimen HCM-SANG-0277-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0277-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0277-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c3849ff8-ada4-4044-9edd-941e2a3843f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0277-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/70908c03-535d-471b-931e-f5466c53482f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2,787; copy number 2: 51,818; copy number 3: 2,619; copy number 4: 1,672; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr15:67,063,763–67,521,844, 6 genes (within-gene range 0–2): SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.
- chr20:30,484,925–30,816,274, 4 genes, copy number 5: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Autosomal genes at a single copy (total copy number 1): 443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
